Surgical pathology report (de-identified scan), TCGA case TCGA-HW-7495, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site MSKCC, specimen TCGA-HW-7495-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Location:

Service:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right frontal intra-axial primary brain tumor. Diffusely infiltrating glioma without enhancement on MRI.

Specimens Submitted:

1: Right frontal brain tumor

2: Right frontal lobe brain tumor #2

3: Right frontal lobe brain tumor # 3

4: Right frontal lobe brain tumor #4

DIAGNOSIS:

1. Right frontal brain tumor

Part # 1

TUMOR TYPE:

Oligodendroglioma

WHO GRADE:

II

2. Right frontal lobe brain tumor #2:

Part # 2

TUMOR TYPE:

Oligodendroglioma

WHO GRADE:

II

MOLECULAR TESTING / IMMUNOHISTOCHEMISTRY:

1p/19q FISH has been ordered and results will be issued in a separate report

3. Right frontal lobe brain tumor # 3

Part # 3

TUMOR TYPE:

Oligodendroglioma

WHO GRADE:

II

4. Right frontal lobe brain tumor #4:

Part # 4

TUMOR TYPE:

Oligodendroglioma

WHO GRADE:

II

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	

Gross Description:

1. The specimen is received fresh for frozen section consultation, labeled "right frontal brain tumor" and consists of tan soft tissue fragment measuring 0.3 cmx0.3cmx0.2cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2. The specimen is received fresh labeled, "right frontal lobe brain tumor # 2", and consists of multiple pieces of gray tan friable soft tissue measuring 2.6 x 2.2 x 1.1 cm in aggregate. A sample is submitted to [REDACTED]. The remainder of the specimen is entirely submitted.

Summary of sections:
U - undesignated

3. The specimen is received fresh for frozen section consultation, labeled "right frontal brain tumor#3" and consists of tan soft tissue fragment measuring 0.4 cmx0.2cmx0.2cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

4. The specimen is received fresh labeled, "right frontal brain tumor # 4", and consists of two pieces of gray tan friable soft tissue measuring 1.2 x 0.7 x 0.5 cm and 1.7 x 0.9 x 0.5 cm. A sample is submitted to [REDACTED]. The remainder of the specimen is entirely submitted.

Summary of sections:
U - undesignated

Summary of Sections:

Part 1: Right frontal brain tumor [REDACTED]

Block	Sect. Site	PCs
1	FSC	1

Part 2: Right frontal lobe brain tumor #2

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
6	U	7

Part 3: Right frontal lobe brain tumor # 3

Block	Sect. Site	PCs
1	FSC	1

Part 4: Right frontal lobe brain tumor #4

Block	Sect. Site	PCs
3	U	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen section diagnosis: Right frontal brain tumor Glioma, no overtly high-grade features identified.
Permanent diagnosis: Oligodendroglioma, WHO II
3. Frozen section diagnosis: Right frontal lobe brain tumor # 3 White matter with scattered atypical cells, insufficient for diagnosis
Permanent diagnosis: Oligodendroglioma, WHO II

Source: NCI Genomic Data Commons file d42be726-e0ac-4462-b4a0-84da506514c8 (TCGA-HW-7495.C5AD0F30-8B83-4D3B-B695-C177F251EBC6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).